Somatic mutation profile of tumor specimen TCGA-P3-A5QA-01A (aliquot TCGA-P3-A5QA-01A-11D-A28R-08) from TCGA case TCGA-P3-A5QA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 41.4 years (15,125 days).
Specimen TCGA-P3-A5QA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 975845fc-879a-46cd-a45f-f3e723bbd3ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A5QA-10A (Blood Derived Normal), aliquot TCGA-P3-A5QA-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0129525-81c8-44be-a2d5-fcab50084b92

The open-access MAF lists 73 somatic variants for this specimen: 60 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 12, Nonsense Mutation 5, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.85_102del p.R29_A34del | In Frame Del (DEL) | VAF 28/126 reads (22%) | hotspot (GDC flag); called by pindel, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 35/72 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.3727C>T p.R1243C (on ENST00000506720 / NM_001322402.2; = p.R1175C on NM_015236.6) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222861886, COSV101547399; called by muse, mutect2, varscan2
- AGAP1 | c.1936G>A p.E646K (on ENST00000304032 / NM_001037131.3; = p.E593K on NM_014914.5) | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs376727493; called by muse, mutect2, varscan2
- AGRN | c.4573G>A p.V1525I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs779716690, COSV101039090; called by muse, mutect2
- ANKRD11 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.085); catalogued as COSV99970646; called by muse, mutect2, varscan2
- BIRC6 | c.12410C>T p.A4137V | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.3); catalogued as rs777191070, COSV101428938; called by muse, mutect2, varscan2
- BRAP | c.950G>A p.C317Y | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554274; called by muse, mutect2, varscan2
- C1orf112 | c.383C>A p.A128D | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99610202; called by muse, mutect2
- CA10 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780641204, COSV53353383; called by muse, mutect2, varscan2
- CDKN2A | c.130dup p.Y44Lfs*76 | Frame Shift Ins (INS) | VAF 35/233 reads (15%) | catalogued as COSV58682773, COSV58689669, COSV58711803, COSV58713131; called by pindel, varscan2
- CFH | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs371192606, CM104000; called by muse, mutect2, varscan2
- CLDN10 | c.272T>C p.F91S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100176281; called by muse, mutect2, varscan2
- CPM | c.917A>G p.E306G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV100615275; called by muse, mutect2, varscan2
- CYP2J2 | c.603T>G p.F201L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100968133; called by muse, mutect2, varscan2
- DCUN1D5 | c.194T>G p.V65G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV99499264; called by muse, mutect2
- DNAI2 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs753933951, COSV100210033, COSV56756568; called by muse, mutect2, varscan2
- GALNT2 | c.1652G>A p.S551N | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV100795907; called by muse, mutect2, varscan2
- IGSF9B | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as rs770027773, COSV100318465; called by mutect2, varscan2
- INTS5 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 30/200 reads (15%) | catalogued as COSV100399829; called by muse, mutect2, varscan2
- KCNH4 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs751569305, COSV52920746; called by muse, mutect2, varscan2
- KCTD19 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1403214260, COSV100431231; called by muse, mutect2, varscan2
- KRT14 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV99391188; called by muse, mutect2
- MRC1 | c.3223C>T p.R1075* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as rs922406253; called by muse, mutect2, varscan2
- NAT8 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs1232793233, COSV99722086; called by muse, mutect2, varscan2
- NLRP13 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100738537; called by muse, mutect2, varscan2
- OCA2 | c.1444A>C p.T482P | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100668694; called by muse, mutect2, varscan2
- OR2B6 | c.782A>C p.Q261P | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99773852; called by muse, mutect2, varscan2
- OR2L8 | c.832A>C p.T278P | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100594323; called by muse, mutect2, varscan2
- OR51F1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs536873822, COSV58580427; called by muse, mutect2
- OR6C65 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101110209; called by muse, mutect2, varscan2
- PCDHA10 | c.1541G>A p.G514D | Missense Mutation (SNP) | VAF 51/257 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554150286, COSV100254568; called by muse, mutect2, varscan2
- PEX12 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as COSV99862249; called by muse, mutect2, varscan2
- PNPLA6 | c.1853C>T p.A618V (on ENST00000414982 / NM_001166111.2; = p.A570V on NM_006702.5) | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.26); catalogued as COSV99654536; called by muse, mutect2, varscan2
- PRDM9 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as rs375716818; called by muse, mutect2
- PRKCA | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as rs878902960, COSV52581940; called by muse, mutect2, varscan2
- PRSS48 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs188453537, COSV71614116; called by muse, mutect2, varscan2
- RAPH1 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs76891512, COSV99864530; called by muse, mutect2, varscan2
- RHD | c.491A>G p.D164G | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as COSV100155289; called by muse, mutect2, varscan2
- SDK1 | c.2834T>A p.F945Y | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV101269876; called by muse, mutect2, varscan2
- SDK1 | c.3991C>T p.R1331* | Nonsense Mutation (SNP) | VAF 24/129 reads (19%) | catalogued as rs764694117, COSV101269877; called by muse, mutect2, varscan2
- SEMA5A | c.2443G>T p.E815* | Nonsense Mutation (SNP) | VAF 21/143 reads (15%) | catalogued as COSV101228733, COSV66790730; called by muse, mutect2, varscan2
- SLC25A43 | c.825G>A p.K275= | Splice Region (SNP) | VAF 9/104 reads (9%) | catalogued as COSV99474777; called by muse, mutect2
- SLC9C1 | c.2057G>T p.G686V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99998837; called by muse, mutect2, varscan2
- SLCO6A1 | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1449434352, COSV101135010; called by muse, mutect2, varscan2
- SPATA31D1 | c.2155A>C p.I719L | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100783058; called by muse, mutect2
- SPTA1 | c.6889C>T p.R2297W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375016862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STOML1 | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100382057; called by muse, mutect2, varscan2
- THOP1 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310798; called by muse, mutect2
- TJAP1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs149220687; called by muse, mutect2, varscan2
- TMC4 | c.511C>T p.L171F (on ENST00000617472 / NM_001145303.3; = p.L165F on NM_144686.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99825075; called by muse, mutect2, varscan2
- TMEM168 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760899014, COSV57179224; called by muse, mutect2, varscan2
- TRAT1 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99849566; called by mutect2, varscan2
- TRIM36 | c.37A>C p.I13L | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs759181130, COSV99142677; called by muse, mutect2
- TXNDC16 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99909679; called by muse, mutect2, varscan2
- YTHDF3 | c.1519T>G p.F507V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV101572427; called by muse, mutect2
- ZC3H4 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.92); catalogued as rs760156897, COSV53413898; called by muse, mutect2, varscan2
- KRT5 | c.1353_1354dup p.E452Vfs*7 | Frame Shift Ins (INS) | VAF 27/232 reads (12%) | called by mutect2, pindel, varscan2
- OR7A5 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.15); called by muse, mutect2
- SLC43A3 | c.584_587del p.V195Afs*6 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | called by pindel, varscan2
- AFDN | c.2430G>T p.L810= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100653561; called by muse, mutect2
- AGRN | c.2904G>A p.P968= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as rs761226422, COSV101039088; called by muse, mutect2, varscan2
- DKKL1 | c.156C>G p.L52= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV99678807; called by muse, mutect2
- ELAVL2 | c.594C>T p.I198= | Silent (SNP) | VAF 42/185 reads (23%) | catalogued as COSV56363971, COSV99807254; called by muse, mutect2, varscan2
- EPPK1 | c.6636G>A p.E2212= | Silent (SNP) | VAF 42/341 reads (12%) | catalogued as rs569459584, COSV73261088; called by muse, mutect2, varscan2
- IFT140 | c.2334C>T p.H778= | Silent (SNP) | VAF 38/200 reads (19%) | catalogued as rs774009074, COSV99560195; called by muse, mutect2, varscan2
- NDST3 | c.1230C>T p.H410= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs748397881, COSV99630190, COSV99631538, COSV99631897; called by muse, mutect2, varscan2
- PCSK2 | c.1236G>A p.L412= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV99360767; called by muse, mutect2
- PNMA8A | c.537C>T p.A179= | Silent (SNP) | VAF 33/212 reads (16%) | catalogued as rs369461089; called by muse, mutect2, varscan2
- SEMA3A | c.327C>T p.D109= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV99547995; called by muse, mutect2, varscan2
- SLC18A3 | c.768G>A p.A256= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs761325222, COSV100340917; called by muse, mutect2
- TNS4 | c.483C>T p.H161= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs755695435, COSV99564160; called by muse, mutect2, varscan2
- IGHV1-12 | n.3G>A | RNA (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
